Somatic mutation profile of tumor specimen TCGA-5A-A8ZG-01A (aliquot TCGA-5A-A8ZG-01A-11D-A46P-09) from TCGA case TCGA-5A-A8ZG, project TCGA-CHOL (Cholangiocarcinoma).
Specimen TCGA-5A-A8ZG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aacae37b-9d23-4cf6-a2d9-a25095171c32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5A-A8ZG-10A (Blood Derived Normal), aliquot TCGA-5A-A8ZG-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba14517a-afdb-4848-879e-a0d21fa1cef1

The open-access MAF lists 20 somatic variants for this specimen: 18 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, In Frame Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FRMD1 | c.43A>G p.T15A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.011); catalogued as rs756973733; called by muse, mutect2, varscan2
- P3H4 | c.1025G>C p.R342P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.808); catalogued as COSV100821276; called by muse, mutect2, varscan2
- SGK1 | c.362_364del p.E121del | In Frame Del (DEL) | VAF 8/52 reads (15%) | catalogued as rs776473640; called by pindel, varscan2
- AFF1 | c.3039G>T p.K1013N | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- ARID2 | c.4565del p.T1522Mfs*13 | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel*, varscan2
- CDC42EP2 | c.164T>G p.I55S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- DHX32 | c.1847T>A p.I616K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- FANCD2 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- FOCAD | c.4173del p.M1391Ifs*4 | Frame Shift Del (DEL) | VAF 27/93 reads (29%) | called by pindel, varscan2
- FOCAD | c.4183G>A p.A1395T | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- FYB1 | c.2050A>C p.K684Q (on ENST00000351578 / NM_199335.5; = p.K730Q on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- INSC | c.1139G>T p.C380F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- KNDC1 | c.1543G>T p.E515* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- MYBPC3 | c.3307C>T p.Q1103* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- RTF2 | c.465A>C p.E155D | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC35E1 | c.1193G>T p.S398I | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TNRC18 | c.2740del p.L914Cfs*24 | Frame Shift Del (DEL) | VAF 9/64 reads (14%) | called by mutect2, pindel, varscan2
- USP9Y | c.3218T>A p.L1073H | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- APOBR | c.2205G>A p.A735= (on ENST00000431282; = p.A744= on NM_018690.4) | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs369577053; called by mutect2, varscan2
- GCNT2 | c.926-35316G>A | Intron (SNP) | VAF 17/88 reads (19%) | catalogued as rs777352725; called by muse, mutect2, varscan2
